Somatic mutation profile of tumor specimen TCGA-EY-A548-01A (aliquot TCGA-EY-A548-01A-11D-A27P-09) from TCGA case TCGA-EY-A548, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 83.6 years (30,544 days).
Specimen TCGA-EY-A548-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e962d213-05b5-4db9-9881-175898cce2f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EY-A548-10A (Blood Derived Normal), aliquot TCGA-EY-A548-10A-01D-A27P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/215e89e4-d770-4e1a-909f-b38a35b246af

The open-access MAF lists 689 somatic variants for this specimen: 550 protein-altering or splice-affecting, 126 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 325, Frame Shift Del 152, Silent 126, Frame Shift Ins 28, Nonsense Mutation 22, In Frame Del 9, Intron 8, Splice Region 7, Splice Site 6, 5'Flank 2, 3'UTR 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.5012del p.N1671Ifs*4 (on ENST00000272895 / NM_173076.3; = p.N1353Ifs*4 on NM_015657.3) | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | catalogued as rs387906285, CD051281; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AR | c.2521C>T p.R841C | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs137852577, CM920093, CM980111, CM993110, COSV101019667; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASXL1 | c.1934del p.G645Vfs*58 | Frame Shift Del (DEL) | VAF 14/37 reads (38%) | hotspot (GDC flag); catalogued as rs750318549; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CDH1 | c.377del p.P126Rfs*89 | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | catalogued as rs1060501215; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CHD8 | c.2626C>T p.R876* (on ENST00000646647 / NM_001170629.2; = p.R597* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as rs1555315679, COSV101303044; ClinVar: pathogenic; called by muse, mutect2, varscan2
- INF2 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267606879, CM100142, COSV53030927, COSV99384391; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IQSEC2 | c.854del p.P285Lfs*21 (on ENST00000642864 / NM_001111125.3; = p.P80Lfs*21 on NM_015075.2) | Frame Shift Del (DEL) | VAF 16/59 reads (27%) | catalogued as rs782460038; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 16/38 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 16/54 reads (30%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 16/42 reads (38%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- MYO3A | c.2180dup p.N727Kfs*9 | Frame Shift Ins (INS) | VAF 16/38 reads (42%) | catalogued as rs769462859; ClinVar: likely pathogenic; called by mutect2, varscan2
- PIGO | c.2361del p.T788Lfs*25 | Frame Shift Del (DEL) | VAF 14/63 reads (22%) | catalogued as rs770591449, COSV99956719; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.800del p.K267Rfs*9 | Frame Shift Del (DEL) | VAF 16/72 reads (22%) | catalogued as rs121913289; ClinVar: pathogenic; called by pindel, varscan2*
- STAT5B | c.1102del p.Q368Rfs*2 | Frame Shift Del (DEL) | VAF 28/44 reads (64%) | catalogued as rs761761205; ClinVar: pathogenic; called by mutect2, varscan2
- TBCK | c.1370del p.N457Tfs*15 (on ENST00000273980 / NM_001163436.4; = p.N394Tfs*15 on NM_033115.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | catalogued as rs746860249, CD164312; ClinVar: pathogenic; called by mutect2, varscan2
- AATF | c.52C>G p.R18G | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.396); catalogued as rs1314896570; called by muse, mutect2, varscan2
- ABCA3 | c.3368G>A p.R1123K | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.646); catalogued as rs760978533, COSV100069178; called by muse, mutect2, varscan2
- ABCC10 | c.1894G>A p.V632M (on ENST00000372530 / NM_001198934.2; = p.V604M on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as rs1460996335, COSV55090009; called by muse, mutect2, varscan2
- AC008676.3 | c.635del p.G212Vfs*24 | Frame Shift Del (DEL) | VAF 15/31 reads (48%) | catalogued as rs748255153; called by mutect2, pindel, varscan2
- ACACB | c.769del p.D257Ifs*17 | Frame Shift Del (DEL) | VAF 7/57 reads (12%) | catalogued as rs768607691; called by mutect2, pindel, varscan2
- ACBD3 | c.568del p.R190Gfs*43 | Frame Shift Del (DEL) | VAF 11/54 reads (20%) | catalogued as rs757016425; called by mutect2, varscan2
- ACSL4 | c.1334del p.P445Rfs*10 (on ENST00000340800 / NM_022977.2; = p.P404Rfs*10 on NM_004458.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 12/45 reads (27%) | catalogued as COSV61615691; called by mutect2, pindel, varscan2
- ACTL7B | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs140561800, COSV65927449; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 53/71 reads (75%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAMTS7 | c.4478G>A p.R1493Q | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.041); catalogued as rs750358699, COSV101183290; called by muse, mutect2, varscan2
- ADAT1 | c.120A>G p.I40M | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as COSV57188071; called by muse, mutect2, varscan2
- ADGRG4 | c.108dup p.G37Wfs*4 | Frame Shift Ins (INS) | VAF 28/94 reads (30%) | catalogued as rs1238901032; called by mutect2, varscan2
- ADGRG7 | c.2255G>A p.R752Q | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs765767252, COSV99841614; called by muse, mutect2, varscan2
- AHDC1 | c.2176C>T p.R726W | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760779235, COSV99899796; called by muse, mutect2
- AIDA | c.910C>T p.H304Y | Missense Mutation (SNP) | VAF 3/51 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.093); catalogued as COSV100388472; called by muse, mutect2
- AKAP14 | c.416T>C p.M139T | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV100538429; called by muse, mutect2, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 15/45 reads (33%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AKR1B15 | c.324G>A p.W108* | Nonsense Mutation (SNP) | VAF 6/137 reads (4%) | catalogued as COSV101423352, COSV71152664; called by muse, mutect2
- ALOX15B | c.1036C>T p.P346S | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101205724, COSV66480335; called by muse, mutect2, varscan2
- ALPG | c.577G>A p.V193M | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as rs199598336, COSV54966617; called by muse, mutect2, varscan2
- AMBRA1 | c.3721C>T p.R1241W (on ENST00000458649 / NM_001367468.1; = p.R1151W on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.353); catalogued as rs772046544, COSV54049799; called by muse, mutect2, varscan2
- ANAPC1 | c.2572C>T p.P858S | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs781660125, COSV100595141; called by muse, mutect2
- ANKRD17 | c.3763G>A p.A1255T | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58223584; called by muse, mutect2, varscan2
- AR | c.1576C>A p.P526T | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV101019662; called by muse, mutect2, varscan2
- ARHGAP35 | c.3825A>G p.T1275= | Splice Region (SNP) | VAF 19/38 reads (50%) | catalogued as COSV101351809; called by muse, mutect2, varscan2
- ARHGAP6 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV100498142; called by muse, mutect2, varscan2
- ARHGEF1 | c.1195C>T p.R399W | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as rs1555848409, COSV61529446; called by muse, mutect2, varscan2
- ARHGEF26 | c.1138T>C p.Y380H | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100726698; called by muse, mutect2, varscan2
- ARHGEF28 | c.1901G>A p.R634Q | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs533525206, COSV99710288; called by muse, mutect2, varscan2
- ARHGEF9 | c.1385G>A p.R462H | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0.136); catalogued as COSV99492477; called by muse, mutect2, varscan2
- ARMH4 | c.984del p.K329Sfs*10 | Frame Shift Del (DEL) | VAF 27/79 reads (34%) | catalogued as rs770964750; called by mutect2, pindel, varscan2
- ASH1L | c.8698del p.T2900Qfs*44 (on ENST00000368346 / NM_001366177.2; = p.T2895Qfs*44 on NM_018489.3) | Frame Shift Del (DEL) | VAF 20/71 reads (28%) | catalogued as rs761154268; called by mutect2, varscan2
- ASTN1 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated, low confidence (0.25); PolyPhen probably damaging (0.989); catalogued as rs533960916, COSV56065847; called by muse, mutect2, varscan2
- ATP13A5 | c.1891G>A p.A631T | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.417); catalogued as COSV100665798; called by muse, mutect2, varscan2
- ATP2B2 | c.2737G>T p.A913S (on ENST00000352432; = p.A879S on NM_001683.5) | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.298); catalogued as COSV100660559; called by muse, mutect2, varscan2
- ATP2B3 | c.3524del p.P1175Rfs*12 | Frame Shift Del (DEL) | VAF 12/29 reads (41%) | catalogued as rs782513834; called by mutect2, pindel, varscan2
- ATXN2L | c.2997del p.Q1002Kfs*50 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | catalogued as rs1288664341; called by mutect2, pindel, varscan2
- B3GALT1 | c.307del p.D103Mfs*10 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | catalogued as rs767927493, COSV100003016; called by mutect2, pindel
- B3GNTL1 | c.110T>C p.L37S | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100302271; called by muse, mutect2, varscan2
- BACE2 | c.305del p.P102Rfs*25 | Frame Shift Del (DEL) | VAF 11/44 reads (25%) | catalogued as rs771098505; called by mutect2, pindel, varscan2
- BACE2 | c.536C>T p.T179I | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.316); catalogued as COSV100161227; called by muse, mutect2, varscan2
- BAMBI | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.346); catalogued as COSV100977548; called by muse, mutect2
- BCAN | c.2439G>A p.V813= | Splice Region (SNP) | VAF 4/25 reads (16%) | catalogued as COSV100228530; called by muse, mutect2
- BCOR | c.676T>C p.S226P | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.993); catalogued as COSV100654266; called by muse, mutect2, varscan2
- BECN1 | c.46T>C p.F16L | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100831191; called by muse, mutect2, varscan2
- BHLHE23 | c.356C>T p.A119V (on ENST00000370346; = p.A135V on NM_080606.4) | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64846439; called by muse, mutect2, varscan2
- BNC1 | c.225del p.M76Cfs*14 | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | catalogued as rs751941533; called by mutect2, pindel, varscan2
- BNIP1 | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs776652848, COSV51571239; called by muse, mutect2, varscan2
- BRD3 | c.71del p.P24Rfs*24 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | catalogued as rs763134487; called by mutect2, varscan2
- BRSK1 | c.1985G>A p.R662H | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.379); catalogued as COSV100474711; called by muse, mutect2, varscan2
- BTRC | c.1097+1G>A p.X366_splice (on ENST00000370187 / NM_033637.4; = p.X330_splice on NM_003939.5) | Splice Site (SNP) | VAF 28/66 reads (42%) | catalogued as COSV100927941; called by muse, mutect2, varscan2
- C10orf53 | c.272A>G p.N91S | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV100934945; called by muse, mutect2, varscan2
- C11orf54 | c.229-1G>T p.X77_splice | Splice Site (SNP) | VAF 16/42 reads (38%) | catalogued as COSV100487128; called by muse, mutect2, varscan2
- CACNG3 | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1204864111, COSV50065422; called by muse, mutect2, varscan2
- CAMK2B | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.057); catalogued as rs1049233035, COSV51666894; called by muse, mutect2, varscan2
- CAPN13 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs370626547; called by muse, mutect2, varscan2
- CARS1 | c.2009G>A p.R670Q | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as rs772425370, COSV53455169; called by muse, mutect2, varscan2
- CCDC14 | c.1046G>A p.C349Y (on ENST00000488653; = p.C301Y on NM_022757.5) | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV100113485; called by muse, mutect2, varscan2
- CCDC59 | c.454A>G p.K152E | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs766749577, COSV99810848; called by muse, mutect2, varscan2
- CCDC88C | c.4495C>T p.R1499C | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs374862964; called by muse, mutect2, varscan2
- CCHCR1 | c.1912C>T p.R638C | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748422751, COSV52535330; called by muse, mutect2, varscan2
- CCM2 | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs756126156, COSV99348193; called by muse, mutect2, varscan2
- CCNA2 | c.1132C>T p.R378* | Nonsense Mutation (SNP) | VAF 8/48 reads (17%) | catalogued as COSV54666909, COSV99697188; called by muse, mutect2, varscan2
- CCP110 | c.2435G>A p.R812H | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756544114, COSV101195353; called by muse, mutect2, varscan2
- CD109 | c.1174A>T p.T392S | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV99754776; called by muse, mutect2, varscan2
- CD22 | c.2083T>C p.C695R | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs1358621384, COSV99323829; called by muse, mutect2, varscan2
- CDCA7L | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60983497; called by muse, mutect2, varscan2
- CDH11 | c.1670G>A p.R557H | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs185190786, COSV51763570; called by muse, mutect2, varscan2
- CENPI | c.698C>A p.P233H | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as COSV99515903; called by muse, mutect2, varscan2
- CEP128 | c.1126G>A p.A376T | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs769253255, COSV53674195; called by muse, mutect2, varscan2
- CEP131 | c.2945C>T p.A982V (on ENST00000269392 / NM_001319228.2; = p.A979V on NM_014984.4) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780940898, COSV99489103; called by muse, mutect2, varscan2
- CFAP126 | c.227del p.P76Lfs*4 | Frame Shift Del (DEL) | VAF 29/83 reads (35%) | catalogued as rs780823798; called by mutect2, pindel, varscan2
- CFAP206 | c.1430del p.N477Ifs*4 | Frame Shift Del (DEL) | VAF 16/42 reads (38%) | catalogued as rs751492244; called by mutect2, varscan2
- CHD8 | c.7112del p.N2371Ifs*6 (on ENST00000646647 / NM_001170629.2; = p.N2092Ifs*6 on NM_020920.4) | Frame Shift Del (DEL) | VAF 20/66 reads (30%) | catalogued as rs751094013; called by mutect2, varscan2
- CHRNA2 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0.019); catalogued as rs759595350, COSV99532564; ClinVar: likely benign; called by muse, mutect2, varscan2
- CHRNA3 | c.814_816del p.K272del | In Frame Del (DEL) | VAF 22/71 reads (31%) | catalogued as rs1423035143; called by mutect2, pindel, varscan2
- CHST1 | c.1007C>T p.T336M | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57326043; called by muse, mutect2, varscan2
- CHST12 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as rs149493991; called by muse, mutect2, varscan2
- CHUK | c.1783C>T p.Q595* | Nonsense Mutation (SNP) | VAF 9/25 reads (36%) | catalogued as COSV100957061; called by muse, mutect2, varscan2
- CIBAR2 | c.535C>T p.Q179* | Nonsense Mutation (SNP) | VAF 7/72 reads (10%) | catalogued as COSV101608299; called by muse, mutect2
- CIT | c.1856C>T p.P619L | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99951146; called by muse, mutect2, varscan2
- CLDN10 | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.152); catalogued as rs142536284; called by muse, mutect2, varscan2
- CLEC14A | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as COSV100643685; called by muse, mutect2
- CLIC5 | c.569A>T p.N190I (on ENST00000185206 / NM_001370649.1; = p.N31I on NM_016929.5) | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99485478; called by muse, varscan2
- CLRN2 | c.442G>A p.V148M | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs775419982, COSV71825156; called by muse, mutect2, varscan2
- CLTC | c.473C>T p.T158I | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.506); catalogued as COSV99292980; called by muse, mutect2, varscan2
- CLUAP1 | c.122G>A p.W41* | Nonsense Mutation (SNP) | VAF 14/68 reads (21%) | catalogued as rs1487080051, COSV100489815; called by muse, mutect2, varscan2
- COL18A1 | c.3083A>G p.D1028G (on ENST00000359759 / NM_130444.3; = p.D793G on NM_030582.4) | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60587340; called by muse, mutect2, varscan2
- COL5A2 | c.2366G>A p.G789D | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV100880889; called by muse, mutect2, varscan2
- CP | c.2136del p.K712Nfs*4 | Frame Shift Del (DEL) | VAF 12/99 reads (12%) | catalogued as COSV52832190; called by mutect2, pindel, varscan2
- CRACD | c.2729G>A p.R910Q | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.237); catalogued as rs763506093, COSV51720531; called by muse, mutect2, varscan2
- CREBBP | c.2014C>T p.R672C | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99062754; called by muse, mutect2, varscan2
- CREM | c.872T>C p.L291P (on ENST00000429130; = p.L246P on NM_181571.3) | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100415595; called by muse, mutect2, varscan2
- CRIM1 | c.1571C>T p.A524V | Missense Mutation (SNP) | VAF 55/115 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV99754665; called by muse, mutect2, varscan2
- CSF3R | c.628G>A p.G210R | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100118310; called by muse, mutect2, varscan2
- CST4 | c.241del p.V81* | Frame Shift Del (DEL) | VAF 44/128 reads (34%) | catalogued as rs767756120; called by mutect2, pindel, varscan2
- CTCFL | c.75del p.G26Afs*2 | Frame Shift Del (DEL) | VAF 24/79 reads (30%) | catalogued as rs1224759530; called by mutect2, pindel, varscan2
- CTNND2 | c.1412G>A p.R471H | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs774793947, COSV58874187; called by muse, mutect2, varscan2
- CUBN | c.3866G>A p.G1289D | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100913650, COSV64720116; called by muse, mutect2, varscan2
- CYP4F2 | c.1331G>A p.R444H | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138971789; called by muse, mutect2, varscan2
- DCDC1 | c.3414del p.L1140Sfs*36 (on ENST00000597505 / NM_001367979.1; = p.L247Sfs*36 on NM_020869.3) | Frame Shift Del (DEL) | VAF 15/44 reads (34%) | catalogued as COSV60307531, COSV60312679; called by pindel, varscan2
- DCDC1 | c.3376T>C p.F1126L (on ENST00000597505 / NM_001367979.1; = p.F233L on NM_020869.3) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100338847; called by muse, varscan2
- DCDC2B | c.176C>A p.P59H | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99356817; called by muse, mutect2, varscan2
- DCST2 | c.1213dup p.Y405Lfs*30 | Frame Shift Ins (INS) | VAF 8/24 reads (33%) | catalogued as rs774746029; called by mutect2, varscan2
- DDB1 | c.2944G>A p.A982T | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.073); catalogued as rs760408266, COSV100074888; called by muse, mutect2, varscan2
- DDX31 | c.532del p.M178Cfs*42 | Frame Shift Del (DEL) | VAF 39/101 reads (39%) | catalogued as rs1352828170; called by mutect2, pindel, varscan2
- DGKZ | c.773C>T p.P258L (on ENST00000454345 / NM_001105540.2; = p.P69L on NM_003646.4) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs138240327; called by muse, mutect2, varscan2
- DGKZ | c.1749G>A p.G583= (on ENST00000454345 / NM_001105540.2; = p.G395= on NM_003646.4) | Splice Region (SNP) | VAF 22/54 reads (41%) | catalogued as COSV100552058; called by muse, mutect2, varscan2
- DICER1 | c.5113G>A p.E1705K | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58615252, COSV58618257; called by muse, mutect2, varscan2
- DLGAP3 | c.254del p.G85Vfs*215 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | catalogued as rs762874947; called by mutect2, varscan2
- DNAH17 | c.1340del p.G447Afs*11 | Frame Shift Del (DEL) | VAF 14/41 reads (34%) | catalogued as COSV101102038; called by mutect2, pindel, varscan2
- DNER | c.1823C>T p.P608L | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs368405241, COSV59171289; called by muse, mutect2, varscan2
- DNHD1 | c.13594C>T p.R4532C | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as rs1453485435, COSV54432610; called by muse, mutect2, varscan2
- DRAP1 | c.413C>T p.S138L | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.953); catalogued as rs1228881174, COSV56990051; called by muse, mutect2
- DRC7 | c.1557G>A p.M519I | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.39); catalogued as COSV100395935; called by muse, mutect2, varscan2
- DRD5 | c.140T>C p.L47P | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100432071; called by muse, mutect2, varscan2
- DSE | c.230C>T p.T77M | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.407); catalogued as rs150685110; called by muse, mutect2, varscan2
- DSEL | c.1355del p.G452Dfs*7 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | catalogued as COSV59491427; called by mutect2, pindel, varscan2
- DZIP1 | c.2328del p.E777Kfs*6 (on ENST00000347108; = p.E758Kfs*6 on NM_014934.5) | Frame Shift Del (DEL) | VAF 24/100 reads (24%) | catalogued as rs1234396729; called by mutect2, pindel, varscan2
- DZIP1L | c.1741G>T p.G581C | Missense Mutation (SNP) | VAF 89/171 reads (52%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.754); catalogued as COSV100551771; called by muse, mutect2, varscan2
- EBPL | c.516del p.F172Lfs*7 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | catalogued as rs369293935; called by mutect2, varscan2
- EFHC2 | c.1314dup p.A439Cfs*10 | Frame Shift Ins (INS) | VAF 14/42 reads (33%) | catalogued as rs752671785; called by mutect2, varscan2
- EIF4G1 | c.3589C>T p.R1197W (on ENST00000346169 / NM_198241.3; = p.R1002W on NM_004953.5) | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs113388242, CM117031; called by muse, mutect2, varscan2
- ELAC2 | c.2339A>G p.E780G | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV99311608; called by muse, mutect2, varscan2
- ENAH | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.689); catalogued as rs138096201; called by muse, mutect2, varscan2
- ENOPH1 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752920017, COSV56732665; called by muse, mutect2, varscan2
- ENOX1 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV99817425; called by muse, mutect2, varscan2
- ENOX1 | c.644A>G p.H215R | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99817426; called by muse, mutect2, varscan2
- ENTPD7 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV100978503; called by muse, mutect2
- EPB41L5 | c.236T>A p.I79N | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV99759301; called by muse, mutect2, varscan2
- EPS8L1 | c.1082G>C p.G361A (on ENST00000201647 / NM_133180.3; = p.G234A on NM_017729.3) | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99137236; called by muse, mutect2, varscan2
- ERGIC3 | c.464G>A p.C155Y | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV54141525, COSV99650758; called by muse, mutect2, varscan2
- FAH | c.205A>G p.S69G | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV99930584; called by muse, mutect2, varscan2
- FAM3B | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.013); catalogued as rs750575195, COSV100783785; called by muse, mutect2, varscan2
- FAM47B | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as rs760241906, COSV100264679; called by muse, mutect2, varscan2
- FAM71B | c.1768A>G p.M590V | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100262335; called by muse, mutect2, varscan2
- FAT2 | c.631G>A p.V211I | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.245); catalogued as rs201835676; called by muse, mutect2, varscan2
- FBLN5 | c.896G>A p.C299Y | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99970038; called by muse, mutect2, varscan2
- FBN3 | c.4966C>T p.H1656Y | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV99561955; called by muse, mutect2
- FER1L5 | c.5390T>C p.M1797T (on ENST00000623019; = p.M1761T on NM_001293083.2) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.236); catalogued as COSV99383668; called by muse, mutect2, varscan2
- FERMT1 | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 12/33 reads (36%) | catalogued as rs765716291, CM0910121, COSV54095691; called by muse, mutect2, varscan2
- FGD5 | c.1391G>A p.C464Y | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs1468674149, COSV99549451; called by muse, mutect2, varscan2
- FGFR2 | c.656A>G p.E219G | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1390042185, COSV100337348; called by muse, mutect2, varscan2
- FIBCD1 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.076); catalogued as rs767273025, COSV99447584; called by muse, mutect2, varscan2
- FMO3 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.162); catalogued as COSV100882561; called by muse, mutect2
- FOXD4L1 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 23/188 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1315600351, COSV52074099; called by muse, mutect2, varscan2
- FOXD4L3 | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.097); catalogued as COSV100731040; called by mutect2, varscan2
- FRAS1 | c.3053G>A p.C1018Y | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99356159; called by muse, mutect2, varscan2
- FRMD4A | c.3014del p.P1005Qfs*8 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | catalogued as rs752538869; called by mutect2, pindel, varscan2
- FZR1 | c.1105G>A p.G369R | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as rs1354267714, COSV100553919; called by muse, mutect2, varscan2
- GBP4 | c.349G>T p.G117C | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100864478; called by muse, mutect2, varscan2
- GBP7 | c.1885C>G p.L629V | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.071); catalogued as COSV99643557; called by muse, mutect2, varscan2
- GGN | c.1741C>T p.R581C | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.88); catalogued as rs1476347261, COSV99287653; called by muse, mutect2, varscan2
- GIGYF1 | c.331del p.L111Wfs*234 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as rs763147690; called by mutect2, varscan2
- GJB4 | c.470A>G p.D157G | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as COSV100258730; called by muse, mutect2, varscan2
- GLI1 | c.821del p.G274Afs*6 | Frame Shift Del (DEL) | VAF 6/48 reads (13%) | catalogued as rs759448855, COSV99954330; called by mutect2, pindel, varscan2
- GNAQ | c.783C>G p.Y261* | Nonsense Mutation (SNP) | VAF 19/62 reads (31%) | catalogued as COSV99682096; called by muse, mutect2, varscan2
- GPATCH8 | c.3545del p.P1182Qfs*22 | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | catalogued as COSV59193518; called by mutect2, pindel, varscan2
- GPC1 | c.673C>T p.Q225* | Nonsense Mutation (SNP) | VAF 32/55 reads (58%) | catalogued as COSV99883270; called by muse, mutect2, varscan2
- GPC5 | c.1637C>T p.T546I | Missense Mutation (SNP) | VAF 60/138 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as COSV100996218; called by muse, mutect2, varscan2
- GPER1 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.849); catalogued as rs1182360006, COSV99867451; called by muse, mutect2, varscan2
- GRB7 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.189); catalogued as rs780450400, COSV58450783; called by muse, mutect2, varscan2
- GRIK3 | c.1595C>T p.S532F | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100902392; called by muse, mutect2, varscan2
- GRIP1 | c.1634G>A p.R545Q (on ENST00000359742 / NM_001379345.1; = p.R493Q on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as rs370175362; called by muse, mutect2, varscan2
- GTDC1 | c.410T>C p.M137T | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs996461060, COSV99602072; called by muse, mutect2, varscan2
- H2AC8 | c.265C>A p.R89S | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV99773431; called by muse, mutect2, varscan2
- H2BC6 | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.133); catalogued as rs751629438, COSV100534510; called by muse, mutect2
- H3C12 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.973); catalogued as COSV58154358; called by muse, mutect2, varscan2
- HAUS8 | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as COSV53727173, COSV99505541; called by muse, mutect2, varscan2
- HDAC9 | c.34T>C p.S12P | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.023); catalogued as COSV101287776; called by muse, mutect2, varscan2
- HINT1 | c.158T>G p.L53R | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100401214; called by muse, mutect2, varscan2
- HIVEP2 | c.4829G>T p.R1610L | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as rs751452135, COSV99175831; called by muse, mutect2, varscan2
- HJURP | c.1727G>A p.R576H | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as rs368958261; called by muse, mutect2, varscan2
- HNF1A | c.1136del p.P379Lfs*5 | Frame Shift Del (DEL) | VAF 19/65 reads (29%) | catalogued as COSV57466638; called by mutect2, pindel, varscan2
- HSPG2 | c.7873G>A p.V2625M | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.655); catalogued as rs777675608, COSV101021345; called by muse, mutect2
- HTR7 | c.1016G>A p.C339Y | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99520346; called by muse, mutect2, varscan2
- ICAM3 | c.668del p.P223Rfs*21 | Frame Shift Del (DEL) | VAF 17/66 reads (26%) | catalogued as rs759151580; called by mutect2, pindel, varscan2
- IFNA14 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as COSV66516396; called by muse, mutect2, varscan2
- IFNB1 | c.497T>C p.I166T | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as rs1477378129, COSV101207840; called by muse, mutect2, varscan2
- IFT43 | c.503G>A p.R168Q (on ENST00000314067 / NM_001102564.3; = p.R173Q on NM_052873.3) | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.506); catalogued as rs369282525; called by muse, mutect2, varscan2
- IKBKB | c.1544G>T p.R515M | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as COSV100645859; called by muse, mutect2, varscan2
- IL17REL | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.811); catalogued as COSV100377487; called by muse, mutect2, varscan2
- IMPDH2 | c.1256C>T p.A419V | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100455218; called by muse, mutect2, varscan2
- INPP5D | c.1253dup p.P419Sfs*27 (on ENST00000445964 / NM_001017915.3; = p.P418Sfs*27 on NM_005541.5) | Frame Shift Ins (INS) | VAF 19/97 reads (20%) | catalogued as rs759837481; called by mutect2, varscan2
- INSM2 | c.1605dup p.S536* | Frame Shift Ins (INS) | VAF 14/47 reads (30%) | catalogued as rs756928018; called by mutect2, varscan2
- INTS1 | c.78C>A p.D26E | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.213); catalogued as COSV101248379; called by muse, mutect2, varscan2
- INTS5 | c.1627G>A p.V543M | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.808); catalogued as COSV100399855; called by muse, mutect2, varscan2
- INTU | c.1207A>G p.M403V | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs369298495; called by muse, mutect2, varscan2
- IRAK1 | c.2097G>T p.Q699H | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.135); catalogued as COSV100889061; called by muse, mutect2, varscan2
- ITGA11 | c.1547A>G p.Y516C | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100242275; called by muse, mutect2, varscan2
- ITGAD | c.2191C>A p.L731I | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV101210601; called by muse, mutect2, varscan2
- ITM2A | c.747C>A p.H249Q | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100964499, COSV64810990; called by muse, mutect2
- ITPR3 | c.2158G>A p.A720T | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.234); catalogued as rs750764933, COSV65408538; called by muse, mutect2
- JUP | c.1624G>A p.V542I | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs571375136, COSV100159843; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNF1 | c.1264G>A p.A422T | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs745849015, COSV54462436; called by muse, mutect2, varscan2
- KCNH8 | c.2352dup p.N785Qfs*3 | Frame Shift Ins (INS) | VAF 6/10 reads (60%) | catalogued as rs760381227; called by mutect2, varscan2
- KCNIP4 | c.460C>T p.R154W | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763059311, COSV100749762; called by muse, mutect2, varscan2
- KCNJ4 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs750087094, COSV100341541; called by muse, varscan2
- KCTD8 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs780193663, COSV63585258; called by muse, mutect2, varscan2
- KIAA1522 | c.2927del p.P976Hfs*70 (on ENST00000373480 / NM_001198972.2; = p.P1035Hfs*70 on NM_020888.3) | Frame Shift Del (DEL) | VAF 11/43 reads (26%) | catalogued as COSV99615233; called by mutect2, pindel, varscan2
- KIF13B | c.2794G>A p.V932I | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.106); catalogued as COSV101580808; called by muse, mutect2, varscan2
- KIF14 | c.583A>C p.K195Q | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.23); catalogued as COSV66261279; called by muse, mutect2, varscan2
- KLHL34 | c.1823C>T p.A608V | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV101070005; called by muse, mutect2, varscan2
- KLK4 | c.490G>A p.V164M | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.847); catalogued as rs777659052, COSV100133555; called by muse, mutect2, varscan2
- KMT2B | c.5273A>G p.Y1758C | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99720780; called by muse, mutect2, varscan2
- KMT2C | c.13488del p.F4496Lfs*21 | Frame Shift Del (DEL) | VAF 18/42 reads (43%) | catalogued as COSV51456416; called by mutect2, pindel, varscan2
- KRR1 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as rs549769836, COSV56991708; called by muse, mutect2, varscan2
- KRT83 | c.1383del p.C462Afs*7 | Frame Shift Del (DEL) | VAF 11/54 reads (20%) | catalogued as COSV99531642; called by mutect2, pindel, varscan2
- KXD1 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1370440647, COSV99723749; called by muse, mutect2, varscan2
- LAMA1 | c.2867C>T p.A956V | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.022); catalogued as COSV101057911; called by muse, mutect2, varscan2
- LAMB2 | c.2597G>A p.R866H | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs745441757, COSV100026542; called by muse, varscan2
- LCTL | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs558143266, COSV100427323; called by muse, mutect2, varscan2
- LETM2 | c.1180G>A p.V394M (on ENST00000379957 / NM_001286819.2; = p.V299M on NM_144652.3) | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV99907645; called by muse, mutect2, varscan2
- LHX4 | c.847G>A p.G283R | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.316); catalogued as rs761944467, COSV99761922; called by muse, mutect2, varscan2
- LINGO4 | c.835A>G p.R279G | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.826); catalogued as COSV100765052; called by muse, mutect2, varscan2
- LMF2 | c.1795C>T p.L599F | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs746641572, COSV53318063; called by muse, mutect2, varscan2
- LMNTD2 | c.156G>A p.P52= | Splice Region (SNP) | VAF 18/67 reads (27%) | catalogued as rs761988792, COSV99529911; called by muse, mutect2, varscan2
- LMO2 | c.209G>A p.R70H (on ENST00000395833 / NM_001142315.2; = p.R139H on NM_005574.4) | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as COSV99137911; called by muse, mutect2, varscan2
- LYG2 | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs146592960; called by muse, mutect2, varscan2
- MAGEE2 | c.133del p.Q45Sfs*27 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | catalogued as rs1159257962; called by mutect2, pindel, varscan2
- MANBA | c.1636C>T p.R546C (on ENST00000642252; = p.R500C on NM_005908.4) | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs763576266, COSV56968724; called by muse, mutect2
- MAP4K4 | c.1699C>T p.R567* (on ENST00000347699 / NM_001242559.2; = p.R536* on NM_004834.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 34/82 reads (41%) | catalogued as COSV100155587; called by muse, mutect2, varscan2
- MAP7D1 | c.68del p.P23Qfs*33 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | catalogued as rs761388884; called by mutect2, pindel, varscan2
- MAPKBP1 | c.2753G>A p.R918Q (on ENST00000456763 / NM_001128608.2; = p.R912Q on NM_014994.3) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs201138035, COSV52968297; called by muse, mutect2, varscan2
- MAST3 | c.2876A>G p.K959R | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.094); catalogued as COSV99446425; called by muse, mutect2
- MEGF8 | c.497del p.G166Vfs*53 | Frame Shift Del (DEL) | VAF 9/56 reads (16%) | catalogued as rs762115034; called by mutect2, pindel, varscan2
- MGAT4B | c.325G>A p.V109M | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.93); catalogued as rs371583458; called by muse, varscan2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 9/33 reads (27%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MLH1 | c.991G>T p.E331* | Nonsense Mutation (SNP) | VAF 29/66 reads (44%) | catalogued as COSV51621048, COSV99212810; called by muse, mutect2, varscan2
- MPP4 | c.938G>T p.R313L | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as COSV100207419; called by muse, mutect2
- MRO | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs866922092, COSV99839586; called by muse, mutect2
- MROH6 | c.1612C>T p.R538C | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs1165764418, COSV101295841; called by muse, mutect2, varscan2
- MRPL15 | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 16/38 reads (42%) | catalogued as rs1181266522, COSV99477648; called by muse, mutect2, varscan2
- MRPS10 | c.83G>A p.G28D | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs772125837, COSV99273680; called by muse, mutect2, varscan2
- MTMR1 | c.1924C>T p.R642C | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs782644695, COSV60939362; called by muse, mutect2, varscan2
- MUC5B | c.4169T>C p.L1390P | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as COSV101500851; called by muse, mutect2, varscan2
- MXRA5 | c.5363C>T p.P1788L | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.766); catalogued as COSV99479576; called by muse, mutect2, varscan2
- MYCL | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as rs746120908, COSV100862404; called by muse, mutect2, varscan2
- MYH14 | c.3932G>T p.G1311V | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV99224319; called by muse, mutect2, varscan2
- MYO1D | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs1009367181, COSV59017463; called by muse, mutect2, varscan2
- MYRF | c.789del p.S264Afs*8 (on ENST00000278836 / NM_001127392.3; = p.S255Afs*8 on NM_013279.4) | Frame Shift Del (DEL) | VAF 21/56 reads (38%) | catalogued as rs769274302, COSV53895135; called by mutect2, varscan2
- NAB2 | c.596_598del p.G199del | In Frame Del (DEL) | VAF 9/60 reads (15%) | catalogued as rs757086139; called by pindel, varscan2
- NCAPG2 | c.412C>T p.R138* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as rs1331986042, COSV99317691; called by muse, mutect2, varscan2
- NDUFS4 | c.473A>C p.K158T | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as rs1262604421, COSV99692495; called by muse, mutect2, varscan2
- NECAP1 | c.545G>T p.G182V | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV100331664, COSV60248983; called by muse, mutect2, varscan2
- NECTIN2 | c.799G>A p.G267S | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); catalogued as rs775484098, COSV99375310; called by muse, mutect2, varscan2
- NEDD1 | c.1414G>T p.E472* | Nonsense Mutation (SNP) | VAF 19/41 reads (46%) | catalogued as COSV99901421; called by muse, mutect2, varscan2
- NKPD1 | c.1460T>C p.F487S | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100521756; called by muse, mutect2, varscan2
- NRAP | c.1256G>A p.R419H (on ENST00000359988 / NM_001322945.2; = p.R384H on NM_006175.4) | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138124439; called by muse, mutect2, varscan2
- NUAK2 | c.1705C>T p.R569W | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs561905076, COSV65682036; called by muse, mutect2, varscan2
- NUMB | c.1238C>T p.S413L (on ENST00000355058; = p.S402L on NM_003744.5) | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs771373657, COSV61572240; called by muse, mutect2, varscan2
- NUP133 | c.2486G>A p.R829Q | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs565984090, COSV99773560; called by muse, mutect2, varscan2
- OR10Z1 | c.265del p.D89Tfs*48 | Frame Shift Del (DEL) | VAF 21/94 reads (22%) | catalogued as rs752054889; called by mutect2, pindel, varscan2
- OR2F1 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 65/143 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs141056144; called by muse, mutect2, varscan2
- OR4C12 | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.236); catalogued as COSV100078710; called by muse, mutect2
- OR52K2 | c.517G>T p.G173C | Missense Mutation (SNP) | VAF 69/160 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100355871; called by muse, mutect2, varscan2
- OSR2 | c.446G>A p.G149D | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV99882863; called by muse, mutect2, varscan2
- OTOF | c.3452C>T p.A1151V (on ENST00000272371 / NM_194248.3; = p.A404V on NM_004802.4) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.175); catalogued as COSV99719179; called by muse, mutect2, varscan2
- P3H4 | c.485T>C p.V162A | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs1555615057, COSV100388041; called by muse, mutect2, varscan2
- PALB2 | c.3518C>T p.A1173V | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.246); catalogued as rs146659762; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PANK4 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs781747436, COSV101022576; called by muse, mutect2
- PAPPA2 | c.5055del p.S1686Vfs*4 | Frame Shift Del (DEL) | VAF 9/81 reads (11%) | catalogued as rs747970462, COSV62809272; called by mutect2, pindel, varscan2
- PATJ | c.5389C>G p.Q1797E | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.054); catalogued as COSV100957706; called by muse, mutect2, varscan2
- PAX1 | c.434G>A p.G145D | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101270393; called by muse, mutect2, varscan2
- PCLO | c.3748C>A p.P1250T | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV100436521, COSV100438612; called by muse, mutect2
- PCNT | c.1444C>T p.Q482* | Nonsense Mutation (SNP) | VAF 9/24 reads (38%) | catalogued as COSV100856096; called by muse, mutect2, varscan2
- PDE4D | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.062); catalogued as rs138291801, COSV72350974; called by muse, mutect2, varscan2
- PDE7B | c.1150C>T p.P384S | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100368385; called by muse, mutect2, varscan2
- PGAM4 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 55/120 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as rs1206734459, COSV100431804; called by muse, mutect2, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 6/19 reads (32%) | catalogued as rs769717544; called by mutect2, varscan2
- PHTF1 | c.478C>T p.R160* | Nonsense Mutation (SNP) | VAF 6/23 reads (26%) | catalogued as rs1249659069, COSV63366711, COSV63367263; called by muse, mutect2
- PHTF1 | c.157G>A p.V53I | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.437); catalogued as rs376636226; called by muse, mutect2, varscan2
- PIK3CG | c.1124G>A p.R375Q | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.6); PolyPhen benign (0.037); catalogued as rs759982158, COSV63245875; called by muse, mutect2, varscan2
- PIK3R4 | c.3422C>T p.S1141L | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs373768958; called by muse, mutect2, varscan2
- PIK3R4 | c.2051G>A p.R684H | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs779956493, COSV100768612; called by muse, mutect2, varscan2
- PIP5K1C | c.1519G>A p.D507N | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100095252; called by muse, mutect2, varscan2
- PIPOX | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 26/65 reads (40%) | catalogued as rs762541074, COSV100038117; called by muse, mutect2, varscan2
- PITPNM1 | c.3223C>T p.R1075C | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99653693; called by muse, mutect2, varscan2
- PKD1L1 | c.992G>T p.G331V | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV99221553; called by muse, mutect2, varscan2
- PKHD1L1 | c.4834G>C p.E1612Q | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0.027); catalogued as COSV101006917; called by muse, mutect2, varscan2
- PLCB2 | c.33del p.K12Rfs*2 | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | catalogued as rs777988967; called by mutect2, pindel, varscan2
- PLEKHS1 | c.1042T>A p.W348R | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100613332; called by muse, mutect2, varscan2
- PNMA3 | c.261del p.W89Gfs*3 | Frame Shift Del (DEL) | VAF 15/37 reads (41%) | catalogued as COSV64722654; called by mutect2, pindel, varscan2
- POMT2 | c.710C>A p.A237D | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV99836733; called by muse, mutect2, varscan2
- POP1 | c.1902+1G>A p.X634_splice | Splice Site (SNP) | VAF 10/103 reads (10%) | catalogued as COSV100856146; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1063C>T p.R355W | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as rs768241040, COSV53450955; called by muse, mutect2, varscan2
- PPARA | c.1109T>G p.L370R | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99415965; called by muse, mutect2
- PPFIA2 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.406); catalogued as rs1170806811, COSV61024823; called by muse, mutect2, varscan2
- PPP1R10 | c.2345G>A p.R782H | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.12); catalogued as rs774652564, COSV64740308; called by muse, mutect2, varscan2
- PPP2R3B | c.1152G>T p.E384D | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs200815029, COSV101180818; called by muse, mutect2, varscan2
- PRLR | c.1533G>T p.E511D | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99184840; called by muse, mutect2
- PROKR1 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs759297385, COSV100375766; called by muse, mutect2, varscan2
- PROSER3 | c.140G>A p.R47K | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1331048229, COSV50000334, COSV99137521; called by muse, mutect2, varscan2
- PSME4 | c.5413del p.T1805Pfs*69 | Frame Shift Del (DEL) | VAF 18/68 reads (26%) | catalogued as COSV101122574; called by mutect2, varscan2
- PTEN | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs746152219, CM1513163, COSV64296809, COSV64296832; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPRS | c.601C>A p.L201M | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99512678; called by muse, mutect2, varscan2
- PTPRT | c.3553G>A p.V1185M | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100630926; called by muse, mutect2, varscan2
- PTX4 | c.797-2A>T p.X266_splice (on ENST00000447419 / NM_001328608.2; = p.X261_splice on NM_001013658.1) | Splice Site (SNP) | VAF 8/19 reads (42%) | catalogued as COSV99560826; called by muse, mutect2, varscan2
- PWWP3B | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.23); catalogued as COSV100531669; called by muse, mutect2, varscan2
- QRICH1 | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as COSV100677000; called by muse, mutect2, varscan2
- R3HDM1 | c.659G>T p.G220V | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99926910; called by muse, mutect2, varscan2
- RAB14 | c.105del p.K35Nfs*18 | Frame Shift Del (DEL) | VAF 12/24 reads (50%) | catalogued as rs1564320972; called by mutect2, varscan2
- RAB9B | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV99686152; called by muse, mutect2
- RAI1 | c.4892C>T p.A1631V | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV99885158; called by muse, mutect2, varscan2
- REN | c.1160G>A p.R387Q | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.414); catalogued as rs371478505; called by muse, mutect2, varscan2
- REST | c.2992G>A p.A998T | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.071); catalogued as COSV100471380; called by muse, mutect2, varscan2
- RFPL4B | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs764420783, COSV101480716; called by muse, mutect2, varscan2
- RGL2 | c.608del p.G203Afs*49 | Frame Shift Del (DEL) | VAF 16/32 reads (50%) | catalogued as rs762949421; called by mutect2, varscan2
- RGL3 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63387128; called by muse, mutect2, varscan2
- RICTOR | c.551T>C p.V184A | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV99705806; called by muse, mutect2, varscan2
- RIN3 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.288); catalogued as COSV99380108; called by mutect2, varscan2
- RNF10 | c.822T>A p.D274E | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as COSV100379028; called by muse, mutect2, varscan2
- RNF151 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs532140313, COSV100364548; called by mutect2, varscan2
- RNF20 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 61/129 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100874338; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 54/83 reads (65%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- ROS1 | c.5782C>A p.L1928I | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV100877754, COSV63861428; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 17/43 reads (40%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPS23 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.077); catalogued as rs1007741926, COSV99688545; called by muse, mutect2
- RPTOR | c.2323G>T p.E775* | Nonsense Mutation (SNP) | VAF 6/47 reads (13%) | catalogued as COSV100157469, COSV60809827, COSV60813916; called by muse, mutect2, varscan2
- RRP8 | c.225C>A p.C75* | Nonsense Mutation (SNP) | VAF 40/90 reads (44%) | catalogued as COSV54450236, COSV99602075; called by muse, mutect2, varscan2
- RUNX1 | c.1150G>A p.A384T (on ENST00000344691 / NM_001001890.3; = p.A411T on NM_001754.5) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.427); catalogued as rs1256594190, COSV100278397; called by muse, mutect2, varscan2
- RYR1 | c.308G>A p.G103D | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62108657; called by muse, mutect2, varscan2
- SAMD5 | c.175G>A p.V59M | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1210819831, COSV100822583, COSV99055011; called by muse, mutect2, varscan2
- SCN1B | c.59del p.G20Afs*15 | Frame Shift Del (DEL) | VAF 22/69 reads (32%) | catalogued as COSV52894984; called by mutect2, pindel, varscan2
- SECISBP2 | c.2267A>G p.Q756R | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100358893; called by muse, mutect2
- SELE | c.1090+2T>C p.X364_splice | Splice Site (SNP) | VAF 5/41 reads (12%) | catalogued as COSV100325198; called by muse, mutect2, varscan2
- SETD7 | c.1026dup p.G343Rfs*6 | Frame Shift Ins (INS) | VAF 10/31 reads (32%) | catalogued as rs35259575; called by mutect2, varscan2
- SETMAR | c.1411C>T p.R471C | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.024); catalogued as rs968658005, COSV100740917; called by muse, mutect2, varscan2
- SEZ6L2 | c.134C>T p.T45M | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as rs139348744; called by muse, mutect2, varscan2
- SFSWAP | c.2564G>T p.R855L | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.165); catalogued as rs777681116, COSV99906256; called by muse, mutect2, varscan2
- SGO1 | c.973del p.M325Cfs*28 | Frame Shift Del (DEL) | VAF 19/42 reads (45%) | catalogued as rs747473028; called by mutect2, varscan2
- SH3TC2 | c.2917G>A p.V973M | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.26); PolyPhen benign (0.171); catalogued as COSV100102436; called by muse, mutect2, varscan2
- SHANK2 | c.3484G>A p.E1162K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.493); catalogued as rs782464725, CM121509, COSV99576435; called by mutect2, varscan2
- SHANK3 | c.641G>A p.S214N | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV99438118; called by muse, mutect2, varscan2
- SHANK3 | c.1265G>T p.S422I | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.185); catalogued as COSV99438121; called by muse, mutect2, varscan2
- SHFL | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs778179423, COSV99464019; called by muse, mutect2, varscan2
- SIPA1L1 | c.3295G>T p.D1099Y | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as COSV100666134, COSV62171115; called by muse, mutect2, varscan2
- SLC12A7 | c.2056del p.H686Tfs*11 | Frame Shift Del (DEL) | VAF 18/107 reads (17%) | catalogued as rs767964038; called by mutect2, pindel, varscan2
- SLC12A9 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV99308260; called by muse, mutect2, varscan2
- SLC17A6 | c.573+1G>C p.X191_splice | Splice Site (SNP) | VAF 24/63 reads (38%) | catalogued as COSV99582490; called by muse, mutect2, varscan2
- SLC26A1 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.932); catalogued as rs749514306, COSV99054011, COSV99926512; called by muse, mutect2, varscan2
- SLC26A8 | c.1039G>A p.V347I | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.055); catalogued as COSV100839637; called by muse, mutect2
- SLC30A7 | c.1060C>T p.Q354* | Nonsense Mutation (SNP) | VAF 10/71 reads (14%) | catalogued as COSV100725619; called by muse, mutect2, varscan2
- SLC38A10 | c.3106A>G p.K1036E | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1381999233, COSV101043494; called by muse, mutect2, varscan2
- SLC41A3 | c.1199C>T p.S400L | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.037); catalogued as rs1559801027, COSV100259902, COSV100260012; called by muse, mutect2, varscan2
- SLC46A3 | c.785_788del p.L262Yfs*5 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | catalogued as rs756174226; called by pindel, varscan2
- SLC4A3 | c.1915C>T p.R639C | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); catalogued as rs770574942, COSV99813310; called by muse, mutect2, varscan2
- SLC5A10 | c.997G>A p.V333M (on ENST00000395645 / NM_001042450.4; = p.V349M on NM_152351.5) | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs540644144, COSV100525568; called by muse, mutect2, varscan2
- SLITRK4 | c.1135G>A p.A379T | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.908); catalogued as COSV100567544; called by muse, mutect2, varscan2
- SMARCAD1 | c.1040del p.N347Mfs*24 | Frame Shift Del (DEL) | VAF 14/45 reads (31%) | catalogued as rs754697669; called by mutect2, varscan2
- SMC1B | c.2419del p.R807Dfs*2 | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | catalogued as COSV62528384; called by mutect2, pindel, varscan2
- SMC6 | c.1228del p.I410Yfs*4 | Frame Shift Del (DEL) | VAF 11/72 reads (15%) | catalogued as rs760667210; called by mutect2, varscan2
- SND1 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as COSV100691247, COSV61244309; called by muse, mutect2, varscan2
- SNX15 | c.191A>G p.Y64C | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100101527; called by muse, mutect2, varscan2
- SORCS3 | c.2710G>A p.A904T | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.377); catalogued as rs1025018871, COSV63795847; called by muse, mutect2, varscan2
- SOX6 | c.1838G>A p.G613D (on ENST00000528429 / NM_001145819.2; = p.G586D on NM_017508.3) | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.183); catalogued as COSV100323392; called by muse, mutect2, varscan2
- SPECC1 | c.818G>A p.S273N | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.694); catalogued as COSV99823004; called by muse, mutect2, varscan2
- SPEG | c.4370G>A p.R1457Q | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.767); catalogued as rs752216303, COSV56678437; called by muse, mutect2, varscan2
- STAT3 | c.1027G>A p.V343I | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.76); catalogued as CM086673, CM127245, COSV52883684; called by muse, mutect2, varscan2
- STX6 | c.415A>G p.K139E | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.24); catalogued as COSV99276137; called by muse, mutect2, varscan2
- SVIL | c.5656G>A p.V1886M (on ENST00000355867 / NM_021738.3; = p.V1460M on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as rs1406921284, COSV63445772; called by muse, mutect2, varscan2
- SVIL | c.3442A>G p.R1148G (on ENST00000355867 / NM_021738.3; = p.R722G on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV100881583; called by muse, mutect2, varscan2
- SYNE1 | c.18128dup p.L6043Ffs*32 (on ENST00000367255 / NM_182961.4; = p.L5972Ffs*32 on NM_033071.3) | Frame Shift Ins (INS) | VAF 12/52 reads (23%) | catalogued as rs1261145534; called by mutect2, pindel, varscan2
- SYNE1 | c.8774C>T p.A2925V (on ENST00000367255 / NM_182961.4; = p.A2932V on NM_033071.3) | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV55134718, COSV99576752; called by muse, mutect2, varscan2
- SYT4 | c.105G>A p.W35* | Nonsense Mutation (SNP) | VAF 8/44 reads (18%) | catalogued as COSV54904109; called by muse, mutect2, varscan2
- SYTL3 | c.1763C>T p.S588L (on ENST00000611299 / NM_001242394.1; = p.S520L on NM_001009991.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs755226340, COSV99792674; called by muse, mutect2, varscan2
- SZT2 | c.6725G>A p.R2242Q (on ENST00000634258 / NM_001365999.1; = p.R2185Q on NM_015284.4) | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs751021759, COSV100987701; called by muse, mutect2, varscan2
- TAB3 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.52); PolyPhen benign (0.106); catalogued as COSV99916889; called by muse, mutect2, varscan2
- TAP1 | c.1711G>A p.A571T | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.204); catalogued as COSV100841330; called by muse, mutect2, varscan2
- TAS1R1 | c.1946T>C p.L649P | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100039908; called by muse, mutect2, varscan2
- TAS2R50 | c.506G>T p.R169M | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.209); catalogued as COSV101115715, COSV67853340; called by muse, mutect2
- TASOR2 | c.4080G>T p.K1360N | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV100051154; called by muse, mutect2, varscan2
- TBC1D4 | c.2824C>T p.P942S | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV100884833; called by muse, mutect2, varscan2
- TBCD | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777029100, COSV100833827; called by muse, mutect2, varscan2
- TBX5 | c.275C>T p.T92M | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV59858456, COSV59860596; called by muse, mutect2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 16/36 reads (44%) | catalogued as rs763321097; called by mutect2, varscan2
- TERT | c.2020G>A p.G674S | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs773813809, COSV57227455; ClinVar: uncertain significance; called by muse, varscan2
- TFB1M | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as rs201089879, COSV99266068; called by muse, mutect2, varscan2
- THOP1 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.738); catalogued as rs142317993; called by muse, mutect2, varscan2
- TJP3 | c.2484del p.Y830Tfs*64 | Frame Shift Del (DEL) | VAF 33/107 reads (31%) | catalogued as rs748320679, COSV99515633; called by mutect2, pindel, varscan2
- TM9SF3 | c.214del p.S72Vfs*31 | Frame Shift Del (DEL) | VAF 18/46 reads (39%) | catalogued as rs760930120; called by mutect2, varscan2
- TMEM163 | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.998); catalogued as COSV56105501, COSV99927276; called by muse, mutect2, varscan2
- TMEM19 | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1028721416, COSV99877179; called by muse, mutect2, varscan2
- TMPO | c.295del p.T99Lfs*12 | Frame Shift Del (DEL) | VAF 25/58 reads (43%) | catalogued as rs770800449; called by mutect2, varscan2
- TMTC2 | c.1412del p.A471Gfs*18 | Frame Shift Del (DEL) | VAF 13/78 reads (17%) | catalogued as COSV58272778; called by mutect2, pindel, varscan2
- TNKS2 | c.3206A>G p.N1069S | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100861167; called by muse, mutect2, varscan2
- TNPO2 | c.640T>C p.F214L | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as COSV100790429; called by muse, mutect2
- TP73 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.087); catalogued as COSV100601665; called by muse, mutect2, varscan2
- TPCN1 | c.1697G>A p.R566Q | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.624); catalogued as rs757630299, COSV100136297, COSV100136978; called by muse, mutect2, varscan2
- TPD52L3 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.846); catalogued as rs764955481, COSV58828304; called by muse, mutect2, varscan2
- TRANK1 | c.5395G>A p.A1799T | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100084968; called by muse, mutect2, varscan2
- TRIM59 | c.604del p.S202Vfs*3 | Frame Shift Del (DEL) | VAF 11/21 reads (52%) | catalogued as rs763112993; called by mutect2, varscan2
- TROAP | c.2323del p.Q775Rfs*? | Frame Shift Del (DEL) | VAF 44/122 reads (36%) | catalogued as COSV57744806; called by pindel, varscan2
- TRPM8 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV61221394; called by muse, mutect2, varscan2
- TRUB1 | c.595dup p.L199Pfs*20 | Frame Shift Ins (INS) | VAF 12/48 reads (25%) | catalogued as rs762997509; called by mutect2, varscan2
- TSHZ1 | c.1444A>G p.S482G (on ENST00000580243 / NM_001308210.2; = p.S437G on NM_005786.6) | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100433965; called by muse, mutect2, varscan2
- TTC3 | c.2334del p.E779Kfs*5 | Frame Shift Del (DEL) | VAF 7/27 reads (26%) | catalogued as rs756650873; called by mutect2, varscan2
- TTL | c.946G>A p.G316S | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs773996151, COSV99271664; called by muse, mutect2, varscan2
- TTLL5 | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs768601418, COSV99709812; called by muse, mutect2, varscan2
- TTLL5 | c.3488G>A p.R1163Q | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.992); catalogued as rs557573661, COSV100091810; called by muse, mutect2, varscan2
- TTN | c.76784T>C p.V25595A (on ENST00000591111; = p.V18171A on NM_003319.4) | Missense Mutation (SNP) | VAF 13/48 reads (27%) | PolyPhen benign (0.003); catalogued as COSV100632806; called by muse, mutect2, varscan2
- TUB | c.298C>T p.R100C (on ENST00000299506 / NM_177972.3; = p.R155C on NM_003320.4) | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.075); catalogued as rs751661721, COSV55109343; called by muse, mutect2, varscan2
- TYW5 | c.54G>C p.Q18H | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs757736149, COSV99705363; called by muse, mutect2, varscan2
- UBA1 | c.3112C>A p.L1038M | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.544); catalogued as COSV100256151; called by muse, mutect2, varscan2
- UGT1A1 | c.1073del p.N358Tfs*8 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | catalogued as CM941353; called by mutect2, pindel, varscan2
- UGT2B15 | c.1054A>T p.T352S | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100592476; called by muse, mutect2, varscan2
- UMODL1 | c.778G>A p.V260I | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs565641987, COSV101248519, COSV68555172; called by muse, mutect2, varscan2
- UNC13B | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); catalogued as COSV101037460; called by muse, mutect2, varscan2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | catalogued as rs767420916; called by mutect2, varscan2
- USP9X | c.7171A>C p.M2391L | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV100200179; called by muse, mutect2, varscan2
- UVSSA | c.1379C>T p.A460V | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.478); catalogued as rs372374507; called by muse, mutect2
- UXT | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.203); catalogued as COSV100243916, COSV60039950; called by muse, mutect2, varscan2
- VAC14 | c.1067C>T p.A356V | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1289872434, COSV55755151, COSV99935147; called by muse, mutect2, varscan2
- VPS28 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as rs1554876052, COSV52873260; called by muse, mutect2, varscan2
- VPS52 | c.1361G>A p.R454H | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.836); catalogued as rs762035393, COSV101460471; called by muse, mutect2, varscan2
- WASF3 | c.909G>C p.Q303H | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as COSV100099655; called by muse, mutect2, varscan2
- WDFY1 | c.486-5_486-3del | Splice Region (DEL) | VAF 14/33 reads (42%) | catalogued as rs1168570073; called by pindel, varscan2
- WDHD1 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775370465, COSV100864431; called by muse, mutect2, varscan2
- WDR55 | c.1022del p.K341Rfs*8 | Frame Shift Del (DEL) | VAF 12/28 reads (43%) | catalogued as rs746919573; called by mutect2, varscan2
- WDTC1 | c.1312C>T p.R438C (on ENST00000319394 / NM_001276252.2; = p.R437C on NM_015023.5) | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100088785; called by muse, mutect2, varscan2
- WIPF2 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.548); catalogued as rs775803870, COSV100063248; called by mutect2, varscan2
- WSCD2 | c.1159C>T p.R387W | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs1248846599, COSV99775343; called by muse, mutect2
- WTAP | c.485G>C p.R162P | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV61610446, COSV61610540; called by muse, mutect2, varscan2
- XPNPEP2 | c.701C>A p.P234Q | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100941299; called by muse, mutect2, varscan2
- XRN1 | c.2080G>A p.V694M | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1461889335, COSV99379029; called by mutect2, varscan2
- ZFYVE26 | c.6287T>C p.L2096P | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as rs367857763; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF43 | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs141039974; called by muse, mutect2, varscan2
- ZNF479 | c.1409G>T p.C470F | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as COSV100483117, COSV58642366; called by muse, mutect2, varscan2
- ZNF532 | c.2765G>A p.R922H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.572); catalogued as rs754386531, COSV60172531; called by muse, mutect2
- ZNF540 | c.445del p.M149Cfs*12 | Frame Shift Del (DEL) | VAF 7/31 reads (23%) | catalogued as COSV100329754, COSV57108094; called by mutect2, pindel, varscan2
- ZNF613 | c.880G>T p.G294* (on ENST00000293471 / NM_001031721.4; = p.G258* on NM_024840.4) | Nonsense Mutation (SNP) | VAF 16/33 reads (48%) | catalogued as COSV99523083; called by muse, mutect2, varscan2
- ZNFX1 | c.2101C>T p.R701W | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as rs371904438; called by muse, mutect2, varscan2
- ABLIM2 | c.1230del p.S411Pfs*17 (on ENST00000341937 / NM_001130084.2; = p.S444Pfs*17 on NM_001130083.2) | Frame Shift Del (DEL) | VAF 24/152 reads (16%) | called by mutect2, pindel, varscan2
- ADAMTS5 | c.1680dup p.Y561Ifs*35 | Frame Shift Ins (INS) | VAF 14/34 reads (41%) | called by mutect2, pindel, varscan2
- AGRN | c.1880del p.P627Rfs*105 | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | called by mutect2, varscan2
- APAF1 | c.1643del p.L548Yfs*3 (on ENST00000551964 / NM_181861.2; = p.L537Yfs*3 on NM_001160.3) | Frame Shift Del (DEL) | VAF 12/68 reads (18%) | called by mutect2, pindel, varscan2
- ARHGAP22 | c.2044del p.S682Rfs*3 | Frame Shift Del (DEL) | VAF 9/41 reads (22%) | called by mutect2, pindel, varscan2
- ARHGEF16 | c.1238del p.G413Afs*8 | Frame Shift Del (DEL) | VAF 7/63 reads (11%) | called by mutect2, pindel, varscan2
- ARHGEF40 | c.4459del p.H1487Tfs*15 | Frame Shift Del (DEL) | VAF 25/61 reads (41%) | called by mutect2, pindel, varscan2
- BEND3 | c.793del p.D265Tfs*54 | Frame Shift Del (DEL) | VAF 28/66 reads (42%) | called by mutect2, varscan2
- C9orf43 | c.884A>G p.Q295R | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.55); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CACNG7 | c.537dup p.A180Cfs*? | Frame Shift Ins (INS) | VAF 13/80 reads (16%) | called by mutect2, pindel, varscan2
- CACTIN | c.382del p.R128Gfs*7 | Frame Shift Del (DEL) | VAF 5/27 reads (19%) | called by mutect2, pindel, varscan2
- CANX | c.80_82dup p.D27dup | In Frame Ins (INS) | VAF 16/94 reads (17%) | called by mutect2, varscan2
- CASP8 | c.34dup p.E12Gfs*6 | Frame Shift Ins (INS) | VAF 16/35 reads (46%) | called by mutect2, pindel, varscan2
- CCDC38 | c.447del p.A150Qfs*24 | Frame Shift Del (DEL) | VAF 32/160 reads (20%) | called by mutect2, pindel, varscan2
- CELSR1 | c.1841del p.G614Afs*54 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | called by mutect2, pindel, varscan2
- CEP350 | c.8326del p.T2776Pfs*21 | Frame Shift Del (DEL) | VAF 4/29 reads (14%) | called by pindel, varscan2
- CHD3 | c.1618del p.R540Vfs*16 | Frame Shift Del (DEL) | VAF 42/75 reads (56%) | called by mutect2, pindel, varscan2
- COL20A1 | c.2331del p.A778Pfs*19 | Frame Shift Del (DEL) | VAF 20/76 reads (26%) | called by mutect2, pindel, varscan2
- COL5A1 | c.4050del p.G1351Efs*137 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | called by mutect2, pindel, varscan2
- CPPED1 | c.652_654del p.D218del | In Frame Del (DEL) | VAF 8/60 reads (13%) | called by pindel, varscan2
- CRB3 | c.327del p.N110Tfs*42 | Frame Shift Del (DEL) | VAF 6/39 reads (15%) | called by mutect2, pindel, varscan2
- CTCF | c.610del p.T204Qfs*18 | Frame Shift Del (DEL) | VAF 7/34 reads (21%) | called by mutect2, pindel, varscan2
- DACH2 | c.182del p.G61Afs*16 | Frame Shift Del (DEL) | VAF 15/87 reads (17%) | called by mutect2, pindel, varscan2
- DENND2D | c.1333_1335del p.P445del | In Frame Del (DEL) | VAF 6/24 reads (25%) | called by pindel, varscan2
- DIS3L2 | c.1835del p.P612Rfs*33 | Frame Shift Del (DEL) | VAF 20/49 reads (41%) | called by mutect2, pindel, varscan2
- DNAJA1 | c.276del p.F92Lfs*22 | Frame Shift Del (DEL) | VAF 16/49 reads (33%) | called by mutect2, pindel, varscan2
- DNM2 | c.2333del p.P778Lfs*7 (on ENST00000355667 / NM_001005360.3; = p.P774Lfs*7 on NM_004945.3) | Frame Shift Del (DEL) | VAF 14/45 reads (31%) | called by mutect2, pindel, varscan2
- DYM | c.1262del p.N421Ifs*10 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | called by mutect2, pindel, varscan2
- ECSIT | c.781del p.Q261Sfs*5 | Frame Shift Del (DEL) | VAF 21/51 reads (41%) | called by mutect2, pindel, varscan2
- EIF4G3 | c.247del p.Q83Nfs*43 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by pindel, varscan2
- EPHX4 | c.515del p.G172Afs*2 | Frame Shift Del (DEL) | VAF 29/102 reads (28%) | called by mutect2, pindel, varscan2
- ERVW-1 | c.68del p.P23Lfs*6 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel, varscan2
- FAM163B | c.206G>A p.G69E | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM178B | c.2026dup p.W676Lfs*41 (on ENST00000490605 / NM_001122646.3; = p.W116Lfs*41 on NM_016490.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 6/17 reads (35%) | called by mutect2, pindel, varscan2
- FANCB | c.1865dup p.L622Ffs*36 | Frame Shift Ins (INS) | VAF 12/23 reads (52%) | called by mutect2, varscan2
- FASN | c.4057del p.L1353Sfs*20 | Frame Shift Del (DEL) | VAF 19/73 reads (26%) | called by mutect2, pindel, varscan2
- FOXG1 | c.1409dup p.L471Tfs*3 | Frame Shift Ins (INS) | VAF 17/48 reads (35%) | called by mutect2, pindel, varscan2
- FSIP2 | c.19115dup p.N6372Kfs*6 | Frame Shift Ins (INS) | VAF 10/18 reads (56%) | called by mutect2, varscan2
- FUBP3 | c.1184del p.P395Lfs*27 | Frame Shift Del (DEL) | VAF 8/56 reads (14%) | called by mutect2, pindel, varscan2
- GPATCH8 | c.1946del p.G649Vfs*460 | Frame Shift Del (DEL) | VAF 8/66 reads (12%) | called by mutect2, pindel, varscan2
- HCFC2 | c.926del p.N309Ifs*32 | Frame Shift Del (DEL) | VAF 14/28 reads (50%) | called by mutect2, varscan2
- HECTD2 | c.309del p.K103Nfs*13 | Frame Shift Del (DEL) | VAF 9/38 reads (24%) | called by mutect2, pindel, varscan2
- HNRNPH2 | c.1142dup p.L381Ffs*14 | Frame Shift Ins (INS) | VAF 10/40 reads (25%) | called by mutect2, varscan2
- INO80D | c.396_397del p.P133Tfs*22 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | called by pindel, varscan2
- IVNS1ABP | c.1136_1137del p.E379Gfs*10 | Frame Shift Del (DEL) | VAF 8/33 reads (24%) | called by pindel, varscan2
- KDM6B | c.3194del p.P1065Rfs*26 | Frame Shift Del (DEL) | VAF 27/64 reads (42%) | called by mutect2, pindel, varscan2
- KHDRBS2 | c.748del p.A250Hfs*60 | Frame Shift Del (DEL) | VAF 15/51 reads (29%) | called by mutect2, pindel, varscan2
- KIAA1549 | c.3525_3527del p.L1176del | In Frame Del (DEL) | VAF 6/40 reads (15%) | called by pindel, varscan2
- KIF13B | c.3485del p.P1162Qfs*16 | Frame Shift Del (DEL) | VAF 15/60 reads (25%) | called by mutect2, pindel, varscan2
- KMT2D | c.5007del p.V1670Sfs*52 | Frame Shift Del (DEL) | VAF 27/60 reads (45%) | called by mutect2, pindel, varscan2
- KRTAP5-7 | c.215del p.G72Afs*103 | Frame Shift Del (DEL) | VAF 31/112 reads (28%) | called by mutect2, pindel, varscan2
- LRPPRC | c.1361del p.N454Mfs*5 | Frame Shift Del (DEL) | VAF 17/65 reads (26%) | called by mutect2, pindel, varscan2
- LTBP2 | c.4171dup p.A1391Gfs*8 | Frame Shift Ins (INS) | VAF 15/65 reads (23%) | called by mutect2, pindel, varscan2
- LYST | c.1455del p.V486* | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | called by mutect2, pindel, varscan2
- MAP7D3 | c.922del p.Q308Rfs*2 | Frame Shift Del (DEL) | VAF 5/36 reads (14%) | called by mutect2, pindel, varscan2
- MEPE | c.694del p.I232Sfs*45 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | called by pindel, varscan2
- MGAT4A | c.632del p.P211Lfs*8 | Frame Shift Del (DEL) | VAF 6/63 reads (10%) | called by mutect2, pindel
- MPDZ | c.1del p.M1? | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | called by mutect2, pindel, varscan2
- MPO | c.1134del p.F379Lfs*55 | Frame Shift Del (DEL) | VAF 12/64 reads (19%) | called by mutect2, pindel, varscan2
- NEB | c.16011del p.E5338Kfs*3 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | called by mutect2, pindel, varscan2
- NELFA | c.859_862del p.K287Lfs*37 (on ENST00000542778; = p.K276Lfs*37 on NM_005663.5) | Frame Shift Del (DEL) | VAF 33/96 reads (34%) | called by mutect2, pindel, varscan2
- NEURL4 | c.3765del p.L1256Cfs*12 | Frame Shift Del (DEL) | VAF 17/84 reads (20%) | called by mutect2, pindel, varscan2
- NOL6 | c.1916del p.G639Afs*10 | Frame Shift Del (DEL) | VAF 37/123 reads (30%) | called by mutect2, pindel, varscan2
- PAX2 | c.1207del p.R403Gfs*37 (on ENST00000428433 / NM_003987.5; = p.R380Gfs*37 on NM_000278.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 16/43 reads (37%) | called by mutect2, pindel, varscan2
- PIP4K2B | c.830T>C p.M277T | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- PIP4K2C | c.54dup p.G19Rfs*43 | Frame Shift Ins (INS) | VAF 49/146 reads (34%) | called by mutect2, pindel, varscan2
- PLEKHA6 | c.982del p.V328Yfs*172 | Frame Shift Del (DEL) | VAF 6/39 reads (15%) | called by mutect2, pindel, varscan2
- PNLIPRP1 | c.1290dup p.K431Qfs*22 | Frame Shift Ins (INS) | VAF 4/23 reads (17%) | called by mutect2, pindel, varscan2
- PODXL | c.480dup p.K161Efs*14 | Frame Shift Ins (INS) | VAF 56/271 reads (21%) | called by mutect2, pindel, varscan2
- POLD2 | c.1148-5_1148-3del | Splice Region (DEL) | VAF 32/80 reads (40%) | called by pindel, varscan2
- PPIG | c.913_914dup p.R306Kfs*21 | Frame Shift Ins (INS) | VAF 6/25 reads (24%) | called by mutect2, varscan2
- RADX | c.1451dup p.N484Kfs*7 | Frame Shift Ins (INS) | VAF 15/47 reads (32%) | called by mutect2, pindel, varscan2
- RANBP2 | c.7587del p.K2529Nfs*25 | Frame Shift Del (DEL) | VAF 90/253 reads (36%) | called by mutect2, pindel, varscan2
- RARS2 | c.1055del p.K352Sfs*10 | Frame Shift Del (DEL) | VAF 13/33 reads (39%) | called by mutect2, pindel, varscan2
- RECQL4 | c.2075_2077del p.L692del | In Frame Del (DEL) | VAF 4/34 reads (12%) | called by pindel, varscan2
- ROCK2 | c.412dup p.W138Lfs*12 | Frame Shift Ins (INS) | VAF 9/23 reads (39%) | called by mutect2, varscan2
- SCAF11 | c.2558del p.K853Rfs*46 | Frame Shift Del (DEL) | VAF 13/46 reads (28%) | called by mutect2, pindel, varscan2
- SCN11A | c.3291del p.F1097Lfs*11 | Frame Shift Del (DEL) | VAF 9/60 reads (15%) | called by mutect2, pindel, varscan2
- SHROOM4 | c.55del p.A19Hfs*34 | Frame Shift Del (DEL) | VAF 24/113 reads (21%) | called by mutect2, pindel, varscan2
- SLC15A2 | c.740del p.P247Lfs*5 | Frame Shift Del (DEL) | VAF 22/48 reads (46%) | called by mutect2, pindel, varscan2
- SLC5A3 | c.78del p.F26Lfs*11 | Frame Shift Del (DEL) | VAF 9/76 reads (12%) | called by mutect2, pindel, varscan2
- SMAD7 | c.626del p.P209Lfs*115 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | called by mutect2, varscan2
- SPATA6 | c.670del p.R224Dfs*17 | Frame Shift Del (DEL) | VAF 43/124 reads (35%) | called by mutect2, pindel, varscan2
- SREBF2 | c.978dup p.K327Qfs*10 | Frame Shift Ins (INS) | VAF 12/37 reads (32%) | called by mutect2, pindel, varscan2
- TBC1D9 | c.628_630del p.E210del | In Frame Del (DEL) | VAF 9/47 reads (19%) | called by mutect2, varscan2
- TGOLN2 | c.828del p.K277Rfs*114 | Frame Shift Del (DEL) | VAF 28/112 reads (25%) | called by mutect2, pindel, varscan2
- TIMP3 | c.602del p.P201Rfs*26 | Frame Shift Del (DEL) | VAF 15/44 reads (34%) | called by mutect2, pindel, varscan2
- TMBIM4 | c.439_441del p.K147del | In Frame Del (DEL) | VAF 12/49 reads (24%) | called by pindel, varscan2
- TMC4 | c.1785_1787del p.L597del (on ENST00000617472 / NM_001145303.3; = p.L591del on NM_144686.4) | In Frame Del (DEL) | VAF 13/40 reads (33%) | called by mutect2, pindel, varscan2
- TMEM131 | c.1920dup p.L641Ifs*6 | Frame Shift Ins (INS) | VAF 12/56 reads (21%) | called by mutect2, varscan2
- TMEM161A | c.801-3del | Splice Region (DEL) | VAF 13/58 reads (22%) | called by mutect2, pindel, varscan2
- TMPRSS2 | c.672del p.K224Nfs*19 | Frame Shift Del (DEL) | VAF 21/57 reads (37%) | called by mutect2, pindel, varscan2
- TOR1AIP1 | c.63del p.R22Gfs*36 | Frame Shift Del (DEL) | VAF 8/27 reads (30%) | called by mutect2, pindel, varscan2
- TRIL | c.1181del p.P394Rfs*30 | Frame Shift Del (DEL) | VAF 10/70 reads (14%) | called by mutect2, pindel, varscan2
- TUBB4A | c.422del p.G141Vfs*24 | Frame Shift Del (DEL) | VAF 36/102 reads (35%) | called by mutect2, pindel, varscan2
- UBXN7 | c.822del p.K274Nfs*9 | Frame Shift Del (DEL) | VAF 17/43 reads (40%) | called by mutect2, pindel, varscan2
- ULK2 | c.834del p.K278Nfs*130 | Frame Shift Del (DEL) | VAF 7/50 reads (14%) | called by mutect2, pindel, varscan2
- USH2A | c.1805del p.G602Efs*34 | Frame Shift Del (DEL) | VAF 18/67 reads (27%) | called by mutect2, pindel, varscan2
- USP28 | c.1579del p.Q527Sfs*12 | Frame Shift Del (DEL) | VAF 8/51 reads (16%) | called by mutect2, pindel, varscan2
- VNN3 | c.600del p.F200Lfs*31 | Frame Shift Del (DEL) | VAF 8/56 reads (14%) | called by mutect2, pindel, varscan2
- WDR47 | c.1250del p.N417Mfs*24 (on ENST00000369962 / NM_001142551.2; = p.N418Mfs*24 on NM_014969.5) | Frame Shift Del (DEL) | VAF 19/57 reads (33%) | called by mutect2, pindel, varscan2
- YY2 | c.669dup p.L224Vfs*5 | Frame Shift Ins (INS) | VAF 16/40 reads (40%) | called by mutect2, pindel, varscan2
- ZBTB41 | c.1870del p.I624Yfs*88 | Frame Shift Del (DEL) | VAF 30/95 reads (32%) | called by mutect2, pindel, varscan2
- ZMYM1 | c.283del p.I95Ffs*49 | Frame Shift Del (DEL) | VAF 7/63 reads (11%) | called by mutect2, pindel, varscan2
- ACAD8 | c.867C>T p.H289= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as rs121908421, CM070641, COSV55539712; called by muse, mutect2, varscan2
- ADAM20 | c.801T>C p.P267= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV99833616; called by muse, mutect2
- ADAMTS10 | c.2961C>T p.P987= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV99547499; called by muse, mutect2, varscan2
- ADGRG4 | c.1782G>T p.V594= | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as COSV99797054; called by muse, mutect2, varscan2
- ADH1C | c.939C>T p.R313= | Silent (SNP) | VAF 43/86 reads (50%) | catalogued as COSV101565188; called by muse, mutect2, varscan2
- AGRP | c.339C>T p.F113= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs766645961, COSV52096872; called by muse, mutect2, varscan2
- AHCTF1 | c.6429G>T p.P2143= (on ENST00000366508; = p.P2117= on NM_015446.5) | Silent (SNP) | VAF 34/125 reads (27%) | catalogued as rs761900985, COSV100404508, COSV58248986; called by muse, mutect2, varscan2
- AKR1C3 | c.234C>T p.D78= | Silent (SNP) | VAF 57/160 reads (36%) | catalogued as COSV101003186; called by muse, mutect2, varscan2
- ANKRD36B | c.960T>C p.S320= | Silent (SNP) | VAF 25/160 reads (16%) | catalogued as COSV99308671; called by muse, mutect2, varscan2
- APLP2 | c.1480C>A p.R494= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as rs756376622, COSV53841655, COSV99600121; called by muse, mutect2, varscan2
- ARCN1 | c.55C>A p.R19= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV99873982; called by muse, mutect2
- ARSL | c.462A>G p.S154= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as COSV101140800; called by muse, mutect2, varscan2
- ATG101 | c.409C>A p.R137= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as COSV61084830; called by muse, mutect2, varscan2
- ATG12 | c.291A>G p.S97= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as rs990095868, COSV99174648; called by muse, mutect2, varscan2
- CAPRIN2 | c.738G>A p.L246= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as COSV99195733; called by muse, mutect2, varscan2
- CARMIL1 | c.3501G>A p.L1167= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV100278930; called by muse, mutect2, varscan2
- CBLN3 | c.87C>T p.A29= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs994941384, COSV99250166; called by muse, mutect2
- CCDC88C | c.1023C>T p.D341= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as rs762008822, COSV66233537; called by muse, mutect2, varscan2
- CCNL2 | c.81C>T p.G27= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs758244726, COSV100785050; called by muse, mutect2, varscan2
- CGB8 | c.39G>A p.L13= | Silent (SNP) | VAF 23/139 reads (17%) | catalogued as COSV100032158; called by muse, mutect2, varscan2
- CHST5 | c.753C>T p.N251= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs1312207104, COSV60336910; called by muse, mutect2, varscan2
- CLCA4 | c.1842C>T p.Y614= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as rs372874690; called by muse, mutect2, varscan2
- CNOT4 | c.1911C>A p.S637= (on ENST00000541284 / NM_001190850.1; = p.S563= on NM_013316.4) | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as COSV100836383; called by muse, mutect2, varscan2
- CNTNAP2 | c.3309C>T p.D1103= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as rs1340600943, COSV62226327; called by muse, mutect2, varscan2
- CNTNAP3 | c.1974G>A p.A658= | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as rs774300042, COSV52668500; called by muse, mutect2, varscan2
- CTDP1 | c.591C>T p.T197= | Silent (SNP) | VAF 35/86 reads (41%) | catalogued as rs762372815, COSV99310625, COSV99311228; called by muse, mutect2, varscan2
- CTDP1 | c.2100C>T p.C700= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs141176127, COSV99311231; called by muse, mutect2, varscan2
- CTNNAL1 | c.1743C>T p.C581= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs372129889; called by muse, mutect2, varscan2
- CTNND1 | c.2277G>T p.L759= (on ENST00000399050 / NM_001085458.2; = p.L753= on NM_001331.3) | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as rs376307021; called by muse, mutect2, varscan2
- DENND2A | c.1410C>T p.D470= | Silent (SNP) | VAF 14/138 reads (10%) | catalogued as COSV99327083; called by muse, mutect2, varscan2
- DMD | c.291T>A p.T97= | Silent (SNP) | VAF 32/82 reads (39%) | catalogued as COSV99926732; called by muse, mutect2, varscan2
- DYNLL1 | c.42G>T p.S14= | Silent (SNP) | VAF 27/57 reads (47%) | catalogued as COSV99655585; called by muse, mutect2, varscan2
- EPHA7 | c.1377C>T p.V459= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as rs373435281, COSV65180335; called by muse, mutect2, varscan2
- FAM111A | c.1725C>T p.G575= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV100659486; called by muse, mutect2, varscan2
- FASN | c.2292C>T p.H764= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs762161225, COSV100148392; called by muse, mutect2, varscan2
- FBLN7 | c.648C>T p.A216= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV99735022; called by muse, varscan2
- FBXW11 | c.312T>C p.H104= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as COSV99441619; called by muse, mutect2, varscan2
- FLG2 | c.6981T>C p.H2327= | Silent (SNP) | VAF 80/212 reads (38%) | catalogued as COSV101166263, COSV66166943; called by muse, mutect2, varscan2
- FLT4 | c.1128C>A p.S376= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV99989278; called by muse, mutect2, varscan2
- FUT1 | c.1026G>A p.E342= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV100038285; called by muse, mutect2, varscan2
- GALR3 | c.282C>T p.V94= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV99968080; called by muse, mutect2, varscan2
- GAS2L2 | c.684G>A p.V228= | Silent (SNP) | VAF 11/36 reads (31%) | called by muse, mutect2, varscan2
- GDE1 | c.492C>T p.C164= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100783245; called by muse, mutect2, varscan2
- GNAZ | c.120C>T p.G40= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV99321282; called by muse, mutect2, varscan2
- GRIK2 | c.1581C>A p.I527= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as COSV100029778; called by muse, mutect2, varscan2
- GRIN2B | c.4008C>T p.Y1336= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as rs764080484, COSV74206890, COSV99078307; called by muse, mutect2, varscan2
- HECTD4 | c.12651C>T p.G4217= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV101108405; called by muse, mutect2, varscan2
- HERC2 | c.8508C>T p.I2836= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs757893230, COSV55350416; called by muse, mutect2, varscan2
- HMCN1 | c.9252C>T p.N3084= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as rs764091385, COSV54878501; called by muse, mutect2, varscan2
- HSD17B12 | c.756G>A p.P252= | Silent (SNP) | VAF 24/107 reads (22%) | catalogued as rs199686029, COSV53502832; called by muse, mutect2, varscan2
- IGSF3 | c.711G>A p.Q237= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as COSV100605160; called by muse, mutect2, varscan2
- IL10RB | c.741C>T p.C247= | Silent (SNP) | VAF 32/74 reads (43%) | catalogued as rs769269032, COSV51614486; called by muse, mutect2, varscan2
- IL17RC | c.9G>A p.V3= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV99925321; called by muse, mutect2
- IL1R1 | c.801T>C p.I267= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as rs767421015, COSV99292926; called by muse, mutect2, varscan2
- ITPR2 | c.1284G>A p.A428= | Silent (SNP) | VAF 33/71 reads (46%) | catalogued as rs199897476; called by muse, mutect2, varscan2
- KCNQ5 | c.747A>G p.G249= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV100573280; called by muse, mutect2, varscan2
- KIAA1217 | c.3240C>T p.T1080= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs373098958; called by muse, mutect2, varscan2
- KIF26B | c.3879G>A p.Q1293= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV100833547; called by muse, mutect2, varscan2
- LAMA2 | c.1248C>T p.C416= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs371944692; ClinVar: likely benign; called by muse, mutect2, varscan2
- LAMTOR2 | c.369G>A p.A123= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs753561651, COSV100737418; called by muse, mutect2, varscan2
- LARGE1 | c.1584C>T p.N528= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as rs113492643; ClinVar: likely benign; called by muse, mutect2
- LTBP4 | c.4269G>A p.E1423= (on ENST00000308370 / NM_001042544.1; = p.E1386= on NM_003573.2) | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as COSV52589727, COSV99199713; called by muse, mutect2, varscan2
- MAN2A2 | c.339G>A p.P113= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as rs745339983, COSV64637374; called by muse, mutect2, varscan2
- MGRN1 | c.375C>T p.D125= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV52151269; called by muse, mutect2, varscan2
- MPST | c.303C>T p.D101= (on ENST00000341116 / NM_001369904.2; = p.D121= on NM_021126.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV99968261; called by muse, mutect2, varscan2
- MRPS26 | c.346C>T p.L116= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV99848724; called by muse, mutect2, varscan2
- MTMR1 | c.1221G>A p.T407= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs144577498, COSV64892628; called by muse, mutect2, varscan2
- MYBPH | c.1161C>T p.P387= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as COSV99704774; called by muse, mutect2, varscan2
- MYO7A | c.819C>T p.G273= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV101289288; called by muse, mutect2, varscan2
- NCKIPSD | c.636G>A p.V212= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV99584318; called by muse, mutect2
- NLRP12 | c.60C>T p.L20= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as rs750274008, COSV100145983; called by muse, varscan2
- NOL6 | c.1329G>C p.L443= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV99955256; called by muse, mutect2, varscan2
- NPEPPS | c.1233C>T p.D411= | Silent (SNP) | VAF 27/110 reads (25%) | catalogued as rs553008169, COSV100444022; called by muse, mutect2, varscan2
- NSD3 | c.1488C>T p.N496= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as COSV100388968; called by muse, mutect2, varscan2
- NUDT13 | c.612G>A p.T204= | Silent (SNP) | VAF 44/86 reads (51%) | catalogued as rs781287511, COSV100624872; called by muse, mutect2, varscan2
- OBSCN | c.13410C>T p.G4470= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as rs375898563, COSV52809071; called by muse, mutect2
- OR10A6 | c.324T>C p.G108= | Silent (SNP) | VAF 23/39 reads (59%) | catalogued as COSV100564369; called by muse, mutect2, varscan2
- OR1Q1 | c.48C>T p.G16= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV99939371; called by muse, mutect2, varscan2
- OR6K3 | c.768T>C p.C256= (on ENST00000368146; = p.C240= on NM_001005327.2) | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV100933899; called by muse, mutect2, varscan2
- OTOP1 | c.963G>A p.V321= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as COSV99588210; called by muse, mutect2, varscan2
- PCDHA3 | c.84C>T p.S28= | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as COSV65367526, COSV65368417; called by muse, mutect2, varscan2
- PCDHA3 | c.1620G>A p.A540= | Silent (SNP) | VAF 48/176 reads (27%) | catalogued as COSV100793595, COSV100793795; called by muse, varscan2
- PCDHA3 | c.1644C>T p.N548= | Silent (SNP) | VAF 26/181 reads (14%) | catalogued as rs782694897, COSV100793797; called by muse, varscan2
- PCDHA8 | c.1629G>A p.P543= | Silent (SNP) | VAF 82/102 reads (80%) | catalogued as rs555722520, COSV65333069, COSV65333143; called by muse, mutect2, varscan2
- PCDHB7 | c.2151G>A p.A717= | Silent (SNP) | VAF 42/220 reads (19%) | catalogued as COSV99176899, COSV99177136, COSV99177482; called by muse, mutect2, varscan2
- PEX5 | c.1758G>A p.Q586= (on ENST00000420616; = p.Q578= on NM_000319.5) | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV99870799, COSV99871351; called by muse, mutect2, varscan2
- PGM5 | c.177C>T p.G59= | Silent (SNP) | VAF 39/110 reads (35%) | catalogued as COSV101123573; called by muse, mutect2, varscan2
- PKP1 | c.1341C>T p.Y447= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV99825779, COSV99825811; called by muse, mutect2, varscan2
- PLA1A | c.829C>T p.L277= | Silent (SNP) | VAF 38/95 reads (40%) | catalogued as COSV99846119; called by muse, mutect2
- PLEKHH3 | c.1338C>T p.F446= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs1214989663, COSV99258074; called by muse, mutect2
- POLR3D | c.24C>T p.G8= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs368686930, COSV60572494; called by muse, mutect2, varscan2
- POM121 | c.894A>G p.S298= (on ENST00000434423; = p.S33= on NM_172020.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 52/129 reads (40%) | catalogued as rs1320721001, COSV99989371; called by muse, mutect2, varscan2
- PTCHD3 | c.870C>T p.H290= | Silent (SNP) | VAF 40/88 reads (45%) | catalogued as rs1292274375, COSV71256851; called by muse, mutect2, varscan2
- SARDH | c.1953C>T p.A651= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs367574128; called by muse, mutect2
- SCTR | c.240G>A p.V80= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as rs759578311, COSV99191766; called by muse, mutect2, varscan2
- SEMA3G | c.978C>T p.Y326= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs149815125; called by mutect2, varscan2
- SERPINB1 | c.33C>T p.F11= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV66313879; called by muse, mutect2, varscan2
- SFMBT2 | c.2550T>C p.I850= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV62805391; called by muse, mutect2, varscan2
- SIRPA | c.591C>T p.N197= | Silent (SNP) | VAF 54/224 reads (24%) | catalogued as rs367635507; called by muse, mutect2, varscan2
- SLC23A1 | c.276C>T p.I92= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as COSV100812117; called by muse, mutect2, varscan2
- SLC41A1 | c.141A>G p.V47= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as COSV100900519; called by muse, mutect2, varscan2
- SMARCC1 | c.2127C>T p.R709= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as rs371760215; called by muse, mutect2, varscan2
- SMCHD1 | c.1923A>G p.V641= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as rs765199144, COSV55260475; called by muse, mutect2, varscan2
- SOGA3 | c.2247C>T p.R749= | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as COSV64105565; called by muse, mutect2, varscan2
- SPATA18 | c.996G>A p.Q332= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as COSV54650369, COSV99731363; called by muse, mutect2, varscan2
- SPOCD1 | c.3498A>G p.L1166= | Silent (SNP) | VAF 38/83 reads (46%) | catalogued as COSV99930406; called by muse, mutect2, varscan2
- SSTR2 | c.837C>T p.S279= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as rs199800631, COSV59535187; called by muse, mutect2, varscan2
- TACR2 | c.1020C>A p.P340= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV100068117; called by muse, mutect2, varscan2
- TASOR | c.1833G>A p.V611= (on ENST00000355628 / NM_001365636.2; = p.V215= on NM_015224.3) | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs772276439, COSV100843709; called by muse, mutect2, varscan2
- TCP11 | c.1032C>T p.S344= (on ENST00000512012; = p.S282= on NM_018679.5) | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as rs773478813, COSV99774528; called by muse, mutect2, varscan2
- TFE3 | c.657G>T p.P219= | Silent (SNP) | VAF 33/72 reads (46%) | catalogued as COSV100252886; called by muse, mutect2, varscan2
- TIE1 | c.79C>T p.L27= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as rs1259803457, COSV100992221; called by muse, mutect2, varscan2
- TKTL2 | c.477C>A p.S159= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV54918220; called by muse, mutect2, varscan2
- TMEM143 | c.49C>T p.L17= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV99507592; called by muse, mutect2, varscan2
- TMTC1 | c.858T>C p.G286= (on ENST00000539277 / NM_001193451.2; = p.G178= on NM_175861.3) | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as rs767777421, COSV99761247; called by muse, mutect2, varscan2
- TNRC6A | c.3951G>A p.G1317= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as COSV100170532; called by muse, mutect2, varscan2
- TPH2 | c.1152T>C p.I384= | Silent (SNP) | VAF 5/58 reads (9%) | catalogued as COSV100422426; called by muse, mutect2
- UHRF1BP1 | c.315C>A p.P105= | Silent (SNP) | VAF 48/124 reads (39%) | catalogued as COSV99512533; called by muse, mutect2, varscan2
- UNC45B | c.567C>T p.D189= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV99269321; called by muse, mutect2, varscan2
- USP17L2 | c.150C>T p.D50= | Silent (SNP) | VAF 25/125 reads (20%) | catalogued as rs755479755, COSV100414776; called by muse, mutect2, varscan2
- WNT10B | c.483G>A p.L161= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV99976097; called by muse, mutect2, varscan2
- XPO7 | c.888C>T p.N296= | Silent (SNP) | VAF 34/94 reads (36%) | catalogued as COSV99382161; called by muse, mutect2, varscan2
- XRRA1 | c.2268G>A p.P756= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs779397174, COSV100213608; called by mutect2, varscan2
- ZNF205 | c.1467G>A p.S489= | Silent (SNP) | VAF 32/80 reads (40%) | catalogued as rs1165681640, COSV54620793; called by muse, mutect2, varscan2
- ZNF217 | c.2889G>A p.S963= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV100184897; called by muse, mutect2, varscan2
- ZNF292 | c.3687C>T p.S1229= | Silent (SNP) | VAF 39/69 reads (57%) | catalogued as rs1311625662, COSV100371424; called by muse, mutect2, varscan2
- A1CF | c.100-6591del | Intron (DEL) | VAF 14/53 reads (26%) | called by mutect2, pindel, varscan2
- ADHFE1 | c.888-317_888-315dup | Intron (INS) | VAF 10/26 reads (38%) | called by mutect2, varscan2
- HLA-F | chr6:29727026 del T | 3'Flank (DEL) | VAF 7/42 reads (17%) | catalogued as COSV52576394; called by mutect2, varscan2
- KHDC4 | c.1266+1335G>T | Intron (SNP) | VAF 20/48 reads (42%) | catalogued as COSV100850861, COSV64164984; called by muse, mutect2, varscan2
- NEK7 | c.198+3306del | Intron (DEL) | VAF 24/58 reads (41%) | catalogued as rs749732874; called by mutect2, pindel, varscan2
- PCDHA5 | c.2352+77del | Intron (DEL) | VAF 4/31 reads (13%) | catalogued as rs781996539; called by mutect2, pindel
- SUPT20HL2 | c.-633C>T | 5'UTR (SNP) | VAF 46/116 reads (40%) | called by muse, mutect2, varscan2
- SZT2 | c.*510T>C | 3'UTR (SNP) | VAF 15/37 reads (41%) | catalogued as COSV100981356; called by muse, mutect2, varscan2
- TIMM50 | chr19:39480591 G>A | 5'Flank (SNP) | VAF 26/48 reads (54%) | catalogued as COSV100068108; called by muse, mutect2, varscan2
- TMEM8B | c.819+28C>T | Intron (SNP) | VAF 59/141 reads (42%) | catalogued as COSV100941638, COSV100941750; called by muse, mutect2, varscan2
- VKORC1 | chr16:31095525 G>A | 5'Flank (SNP) | VAF 9/25 reads (36%) | catalogued as COSV100161869; called by muse, mutect2, varscan2
- ZSCAN32 | c.914+135del | Intron (DEL) | VAF 6/20 reads (30%) | called by mutect2, varscan2
